Gene-level copy-number profile of tumor specimen TCGA-24-1467-01A from TCGA case TCGA-24-1467, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 51.1 years (18,652 days).
Specimen TCGA-24-1467-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.61640eb0-8af4-4f10-99aa-f4fc652f7a36.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1467-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cbf057c8-1032-4145-bb71-fb158020a967

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 10,279; copy number 3: 2,532; copy number 4: 33,869; copy number 5: 8,870; copy number 6: 3,182; copy number 7: 154; copy number 8: 334; copy number 9: 94; copy number 10: 12; copy number 11: 28; copy number 13: 455; copy number 14: 5; copy number 18: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1467-01A-01D-0472-01): tumor purity 0.77, ploidy 3.98, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 597 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:189,486,480–190,569,776, 25 genes, copy number 9 (within-gene range 5–9): KDM3AP1, AC013439.1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179.
- chr3:47,413,681–48,898,904, 58 genes, copy number 9 (within-gene range 5–9): SCAP, AC099778.2, ELP6, BOLA2P2, RN7SL870P, CSPG5, SMARCC1, AC112512.1, HIGD2AP2, DHX30, AC026318.1, MIR1226, MAP4, Y_RNA, VPS26BP1, AC124916.2, RN7SL664P, AC124916.1, CDC25A, SNRPFP4, RNU7-128P, NDUFB1P1, MIR4443, CAMP, ZNF589, MRPS18AP1, Y_RNA, NME6, FCF1P2, SPINK8, MIR2115, FBXW12, RN7SL321P, PLXNB1, CCDC51, TMA7, AC134772.1, ATRIP, TREX1, SHISA5, PFKFB4, MIR6823, UCN2, COL7A1, MIR711, UQCRC1, TMEM89, SLC26A6, MIR6824, CELSR3, MIR4793, LINC02585, AC141002.1, NCKIPSD, IP6K2, PRKAR2A, PRKAR2A-AS1, SLC25A20.
- chr3:160,677,160–161,078,902, 4 genes, copy number 9 (within-gene range 5–9): ARL14, SNORA72, AC069224.1, PPM1L.
- chr7:131,493,964–131,558,217, 3 genes, copy number 11: AC008264.2, PODXL, AC008264.1.
- chr8:76,162,119–76,308,315, 2 genes, copy number 9: AC011029.1, RNU2-54P.
- chr8:99,960,936–100,350,707, 11 genes, copy number 10: RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1.
- chr8:100,382,763–100,382,845, 1 gene, copy number 10: MIR4471.
- chr8:119,832,875–119,855,894, 2 genes, copy number 14 (within-gene range 8–14): AP005717.2, DSCC1.
- chr8:119,862,662–145,066,685, 461 genes, copy number 13–18 (broad region; genes not listed).
- chr13:31,739,526–31,846,539, 2 genes, copy number 9: RXFP2, AL138708.1.
- chr13:31,952,580–31,975,448, 3 genes, copy number 9: EEF1DP3, AC002525.1, Metazoa_SRP.
- chr22:35,066,136–36,028,824, 25 genes, copy number 11 (within-gene range 2–11): ISX, LINC01399, Z99755.2, Z99755.1, RNU7-167P, HMGXB4, AL008635.1, TOM1, MIR3909, MIR6069, Z82244.2, Z82244.1, HMOX1, MCM5, AL022334.1, AL022334.2, RASD2, MB, AL049747.1, APOL6, AL049748.1, MRPS16P3, APOL5, RBFOX2, NDUFA9P1.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
